Somatic mutation profile of tumor specimen 0DT9NJ from CCDI case PBCJLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.9 years (4,337 days).
Specimen 0DT9NJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ee251e3-1766-42a6-83da-cacb4c97ce11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b8df6e0-f699-4ad4-bf1e-3761ef4da51d

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 324/855 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 619/702 reads (88%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- AC100868.1 | c.1640G>T p.R547I | Missense Mutation (SNP) | VAF 189/967 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV51838201; called by muse, mutect2, varscan2
- ADCY6 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 129/358 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs371394102; called by muse, mutect2, varscan2
- GPRC6A | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 274/722 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748772260; called by mutect2, varscan2
- MORN5 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 211/809 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139762512, COSV65649249; called by muse, mutect2, varscan2
- NF1 | c.3586C>T p.L1196F | Missense Mutation (SNP) | VAF 1133/1288 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as CM128890, CM1512952, COSV62222170; called by muse, mutect2, varscan2
- POMGNT1 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 333/745 reads (45%) | PolyPhen benign (0.001); catalogued as rs772158768; called by muse, mutect2, varscan2
- SLC2A13 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 512/1204 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as rs200242923, COSV55115677, COSV99787166; called by muse, mutect2, varscan2
- TCF4 | c.514_517del p.K172Ffs*61 | Frame Shift Del (DEL) | VAF 664/944 reads (70%) | catalogued as rs398123561; called by pindel, varscan2
- ZNF792 | c.1448G>A p.C483Y | Missense Mutation (SNP) | VAF 36/1038 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1428089724, COSV68692783; called by muse, mutect2
- ANKS1A | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 35/718 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- KLK9 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 244/614 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR8U1 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 574/1976 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- OSBPL7 | c.1548C>A p.Y516* | Nonsense Mutation (SNP) | VAF 76/399 reads (19%) | called by muse, mutect2, varscan2
- PROS1 | c.410del p.G137Efs*22 | Frame Shift Del (DEL) | VAF 493/1051 reads (47%) | called by mutect2, pindel, varscan2
- RBMX | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 348/912 reads (38%) | called by mutect2, varscan2
- STAG2 | c.990A>T p.K330N | Missense Mutation (SNP) | VAF 244/1329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SYNJ2 | c.4192A>G p.K1398E | Missense Mutation (SNP) | VAF 250/598 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC191 | c.1242C>T p.G414= | Silent (SNP) | VAF 296/1089 reads (27%) | catalogued as rs752266963, COSV55672240; called by muse, mutect2, varscan2
- ENDOU | c.631C>A p.R211= (on ENST00000422538 / NM_001172439.2; = p.R170= on NM_006025.4) | Silent (SNP) | VAF 48/1230 reads (4%) | called by muse, mutect2
- PAXIP1 | c.2067G>A p.P689= | Silent (SNP) | VAF 403/1055 reads (38%) | catalogued as rs1331949373, COSV101249420, COSV68186789; called by muse, mutect2, varscan2
- AMDHD2 | c.*650_*651del | 3'UTR (DEL) | VAF 159/428 reads (37%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.1590+88G>A | Intron (SNP) | VAF 283/642 reads (44%) | catalogued as rs1040412546; called by muse, mutect2, varscan2
- DTD2 | c.-7T>G | 5'UTR (SNP) | VAF 59/89 reads (66%) | called by muse, varscan2
- RPL31 | c.234-58G>C | Intron (SNP) | VAF 42/196 reads (21%) | catalogued as rs771781539; called by mutect2, varscan2
- TXNRD3 | c.-8_-3dup | 5'UTR (INS) | VAF 28/142 reads (20%) | called by mutect2, varscan2
